Somatic mutation profile of tumor specimen TCGA-99-8032-01A (aliquot TCGA-99-8032-01A-11D-2238-08) from TCGA case TCGA-99-8032, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 62.0 years (22,635 days).
Specimen TCGA-99-8032-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 62d604e0-2250-407f-99d8-ef5a858dcd9c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-99-8032-10A (Blood Derived Normal), aliquot TCGA-99-8032-10A-01D-2238-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e101ac05-6e7f-4158-9050-f60305af13f1

The open-access MAF lists 420 somatic variants for this specimen: 323 protein-altering or splice-affecting, 87 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 260, Silent 87, Nonsense Mutation 34, Frame Shift Del 11, Splice Site 10, Frame Shift Ins 4, Intron 4, RNA 4, Translation Start Site 2, Splice Region 2, 3'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTC1 | c.859C>T p.R287* | Nonsense Mutation (SNP) | VAF 8/75 reads (11%) | catalogued as rs397514660, CM121572, COSV59853125; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 9/45 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA5 | c.653G>T p.R218L | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.934); catalogued as COSV67016596; called by muse, mutect2, varscan2
- ABHD12B | c.1004C>G p.P335R (on ENST00000337334 / NM_001206673.2; = p.P258R on NM_181533.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/302 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.115); catalogued as COSV53585593, COSV53588279; called by muse, mutect2
- ACP1 | c.169G>T p.D57Y | Missense Mutation (SNP) | VAF 41/160 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99681550; called by muse, mutect2, varscan2
- ADAMTS20 | c.1621C>T p.R541C | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs773996468, COSV101239019, COSV67130583; called by muse, mutect2, varscan2
- ADGRG4 | c.2916G>T p.R972S | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as COSV54954887; called by muse, mutect2, varscan2
- ADGRL3 | c.2949C>A p.N983K (on ENST00000506720 / NM_001322402.2; = p.N915K on NM_015236.6) | Missense Mutation (SNP) | VAF 38/267 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72230421; called by muse, mutect2, varscan2
- ADRB3 | c.1175C>T p.A392V | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.165); catalogued as COSV61461881; called by muse, varscan2
- AEBP1 | c.1143G>C p.E381D | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.204); catalogued as COSV56257249; called by muse, mutect2, varscan2
- AGK | c.185A>T p.K62M | Missense Mutation (SNP) | VAF 29/181 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100814735, COSV62594342; called by muse, mutect2, varscan2
- AHNAK | c.176C>T p.T59I | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57211940; called by muse, mutect2, varscan2
- ALKBH5 | c.1069C>T p.R357W | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.796); catalogued as rs767112785, COSV67686945; called by muse, mutect2, varscan2
- ALS2 | c.1765G>T p.G589C | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51886619; called by muse, mutect2, varscan2
- ANKEF1 | c.859C>G p.P287A | Missense Mutation (SNP) | VAF 44/192 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.335); catalogued as COSV101001009, COSV65692338; called by muse, mutect2, varscan2
- ANKRD12 | c.5264C>G p.T1755R | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as COSV50823731; called by muse, mutect2, varscan2
- ANKRD28 | c.2126G>C p.G709A | Missense Mutation (SNP) | VAF 11/294 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.063); catalogued as COSV67517809; called by muse, mutect2
- ARSH | c.919C>A p.L307M | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV66962867; called by muse, mutect2, varscan2
- ASCC3 | c.3384A>T p.R1128S | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV61228029; called by muse, mutect2
- ASGR1 | c.564C>A p.H188Q | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.926); catalogued as COSV52648755; called by muse, mutect2
- ASIC4 | c.647G>T p.R216L | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT tolerated (1); PolyPhen possibly damaging (0.53); catalogued as COSV61731659, COSV61731710; called by muse, mutect2, varscan2
- ATG16L1 | c.1470G>C p.K490N (on ENST00000392017 / NM_030803.7; = p.K471N on NM_017974.4) | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as COSV61465363, COSV61466898; called by muse, mutect2, varscan2
- ATP11A | c.749T>A p.L250Q | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52110724; called by muse, mutect2, varscan2
- ATP1B2 | c.599G>A p.C200Y | Missense Mutation (SNP) | VAF 39/212 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV100006871; called by muse, mutect2, varscan2
- ATP2B2 | c.574T>A p.F192I | Missense Mutation (SNP) | VAF 82/437 reads (19%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.991); catalogued as COSV59495301; called by muse, mutect2, varscan2
- ATP5PB | c.85C>T p.Q29* | Nonsense Mutation (SNP) | VAF 15/78 reads (19%) | catalogued as COSV52385236; called by muse, mutect2, varscan2
- AVPR1A | c.797T>C p.F266S | Missense Mutation (SNP) | VAF 72/291 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.012); catalogued as rs1295525942, COSV54546340; called by muse, mutect2, varscan2
- BCR | c.2237+1G>A p.X746_splice | Splice Site (SNP) | VAF 4/41 reads (10%) | catalogued as COSV59930712; called by muse, mutect2
- BOD1L1 | c.4597G>T p.V1533L | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV50011209; called by muse, mutect2, varscan2
- BPI | c.892G>T p.G298W (on ENST00000262865; = p.G294W on NM_001725.3) | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99480521; called by muse, mutect2, varscan2
- BPI | c.893G>T p.G298V (on ENST00000262865; = p.G294V on NM_001725.3) | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.778); catalogued as COSV99480522; called by muse, mutect2, varscan2
- BRCA2 | c.4621A>G p.K1541E | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as COSV66452895; called by muse, mutect2, varscan2
- BTAF1 | c.539C>T p.S180L | Missense Mutation (SNP) | VAF 31/187 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs1333098112, COSV56433012; called by muse, mutect2, varscan2
- CACNA1A | c.5512G>T p.V1838L | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV64196731; called by muse, mutect2, varscan2
- CACNA1I | c.449G>T p.W150L | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60806876; called by muse, mutect2, varscan2
- CACNA2D1 | c.2001C>A p.C667* (on ENST00000356253 / NM_001366867.1; = p.C655* on NM_000722.4) | Nonsense Mutation (SNP) | VAF 7/23 reads (30%) | catalogued as rs184261698, COSV62378312; called by muse, mutect2, varscan2
- CACNG3 | c.524A>G p.Y175C | Missense Mutation (SNP) | VAF 32/172 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50067323; called by muse, mutect2, varscan2
- CAPN2 | c.1628G>T p.G543V | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54335818; called by muse, mutect2, varscan2
- CD84 | c.504G>T p.W168C | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768041830, COSV100245921; called by muse, mutect2
- CD84 | c.503G>T p.W168L | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100245927; called by muse, mutect2
- CDCA2 | c.2908G>C p.E970Q | Missense Mutation (SNP) | VAF 12/329 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV57945686; called by muse, mutect2
- CDH18 | c.2052G>T p.E684D | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.59); PolyPhen benign (0.01); catalogued as COSV56918494; called by muse, mutect2, varscan2
- CDH4 | c.2401C>A p.Q801K | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.33); catalogued as COSV64652175; called by muse, mutect2, varscan2
- CDHR3 | c.1732G>C p.D578H | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV58414436, COSV58416502; called by muse, mutect2
- CDK12 | c.2941C>T p.R981C | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1300041019, COSV71000453; called by muse, mutect2
- CDS1 | c.1181G>T p.G394V | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55687778; called by muse, mutect2, varscan2
- CEACAM18 | c.227A>T p.H76L | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV67282721; called by muse, mutect2, varscan2
- CELSR3 | c.5851G>C p.A1951P | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.106); catalogued as COSV50853484; called by muse, mutect2, varscan2
- CENPF | c.2059G>T p.D687Y | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100871627; called by muse, mutect2, varscan2
- CEP162 | c.1651C>A p.P551T | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as rs1223670864, COSV100002593; called by mutect2, varscan2
- CFHR5 | c.753T>A p.C251* | Nonsense Mutation (SNP) | VAF 18/52 reads (35%) | catalogued as COSV56821237; called by muse, mutect2, varscan2
- CHD7 | c.8129G>T p.R2710L | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.195); catalogued as COSV71109719; called by muse, mutect2, varscan2
- CHRM4 | c.820G>T p.E274* | Nonsense Mutation (SNP) | VAF 6/18 reads (33%) | catalogued as COSV100708769; called by muse, mutect2
- CMPK2 | c.1050G>T p.Q350H | Missense Mutation (SNP) | VAF 34/172 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV56774547; called by muse, mutect2, varscan2
- CNPY3 | c.373-1G>T p.X125_splice | Splice Site (SNP) | VAF 84/293 reads (29%) | catalogued as COSV65709795; called by muse, mutect2, varscan2
- CNTNAP2 | c.2339C>A p.S780* | Nonsense Mutation (SNP) | VAF 12/59 reads (20%) | catalogued as COSV62173708; called by muse, mutect2, varscan2
- COL19A1 | c.2024C>A p.P675H | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59564803, COSV59571418; called by muse, mutect2, varscan2
- COL21A1 | c.2359G>T p.E787* | Nonsense Mutation (SNP) | VAF 25/90 reads (28%) | catalogued as COSV55160831; called by muse, mutect2, varscan2
- COL22A1 | c.2036C>A p.P679Q | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.259); catalogued as COSV57334492; called by muse, mutect2, varscan2
- COL5A2 | c.1401+1G>T p.X467_splice | Splice Site (SNP) | VAF 11/51 reads (22%) | catalogued as COSV66409175; called by muse, mutect2, varscan2
- CPNE4 | c.153G>T p.K51N | Missense Mutation (SNP) | VAF 48/255 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.022); catalogued as COSV70193659; called by muse, mutect2
- CPXM2 | c.1601G>A p.W534* | Nonsense Mutation (SNP) | VAF 56/240 reads (23%) | catalogued as COSV53860927; called by muse, mutect2, varscan2
- CSMD1 | c.6866C>A p.P2289H (on ENST00000520002; = p.P2288H on NM_033225.6) | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV59316060; called by muse, mutect2, varscan2
- CSMD1 | c.902G>T p.R301L | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); catalogued as rs573237339, COSV68198917; called by muse, mutect2, varscan2
- DAO | c.385G>T p.G129C | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs768551628, COSV57321745, COSV57322288; called by muse, mutect2, varscan2
- DCAF12L1 | c.274C>A p.L92M | Missense Mutation (SNP) | VAF 52/99 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV64421688; called by muse, mutect2, varscan2
- DIDO1 | c.5710C>G p.R1904G | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV56620823; called by muse, varscan2
- DLGAP3 | c.752G>T p.G251V | Missense Mutation (SNP) | VAF 81/262 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.198); catalogued as COSV52393627; called by muse, mutect2, varscan2
- DMKN | c.1105G>T p.G369C | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs758644807, COSV60086076; called by muse, mutect2, varscan2
- DNAH9 | c.9728C>G p.P3243R | Missense Mutation (SNP) | VAF 37/172 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.188); catalogued as COSV52347127; called by muse, mutect2, varscan2
- DNAH9 | c.9831G>C p.E3277D | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.168); catalogued as COSV52347133; called by muse, varscan2
- DOCK2 | c.845A>T p.D282V | Missense Mutation (SNP) | VAF 9/174 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV56955544; called by muse, mutect2
- DOCK5 | c.2879T>G p.L960R | Missense Mutation (SNP) | VAF 39/164 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV52400411; called by muse, mutect2, varscan2
- DPH2 | c.26C>G p.A9G | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.83); PolyPhen benign (0.006); catalogued as COSV52543345; called by muse, mutect2, varscan2
- DSG3 | c.2426C>A p.A809E | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV57125871; called by muse, mutect2, varscan2
- DUS2 | c.811-2A>T p.X271_splice | Splice Site (SNP) | VAF 11/67 reads (16%) | catalogued as COSV62708337; called by muse, mutect2, varscan2
- DUS3L | c.1278G>T p.Q426H | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as COSV57831809; called by muse, mutect2, varscan2
- DUSP10 | c.320G>C p.G107A | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as rs1264841303, COSV60457492; called by muse, mutect2
- DVL2 | c.110G>T p.R37L | Missense Mutation (SNP) | VAF 66/300 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.115); catalogued as COSV50034691, COSV50035608; called by muse, varscan2
- ELAPOR2 | c.1400-1G>T p.X467_splice (on ENST00000450689 / NM_001142749.3; = p.X300_splice on NM_152748.4 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 20/95 reads (21%) | catalogued as COSV51886294, COSV51889819; called by muse, mutect2, varscan2
- EMILIN3 | c.430G>T p.E144* | Nonsense Mutation (SNP) | VAF 25/104 reads (24%) | catalogued as COSV60035987; called by muse, mutect2, varscan2
- EP400 | c.2521A>G p.I841V | Missense Mutation (SNP) | VAF 73/228 reads (32%) | SIFT tolerated (0.83); PolyPhen benign (0.203); catalogued as COSV57770598; called by muse, mutect2, varscan2
- EPHA5 | c.2796G>T p.L932F | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56632908, COSV56642505; called by muse, varscan2
- EPHB3 | c.1206G>C p.Q402H | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV57805576; called by muse, mutect2, varscan2
- ESX1 | c.1132A>T p.R378W | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.77); catalogued as COSV65424244; called by muse, varscan2
- F5 | c.964G>T p.A322S | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as rs1433655859, COSV63123455; called by muse, mutect2, varscan2
- FAM135B | c.2765G>T p.G922V | Missense Mutation (SNP) | VAF 82/193 reads (42%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.039); catalogued as COSV52721139; called by muse, mutect2, varscan2
- FAM135B | c.1942C>A p.L648M | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.641); catalogued as COSV52706750; called by muse, mutect2, varscan2
- FAM90A1 | c.712C>T p.R238* | Nonsense Mutation (SNP) | VAF 19/144 reads (13%) | catalogued as rs768602874, COSV56711813; called by muse, mutect2, varscan2
- FBN2 | c.966C>A p.C322* | Nonsense Mutation (SNP) | VAF 32/152 reads (21%) | catalogued as COSV52509484; called by muse, mutect2, varscan2
- FBXL7 | c.866G>T p.G289V | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV61641140, COSV61645156; called by muse, mutect2, varscan2
- FCGBP | c.11534G>A p.S3845N | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.031); catalogued as rs1255380932; called by muse, mutect2, varscan2
- FCN1 | c.949A>T p.K317* | Nonsense Mutation (SNP) | VAF 32/92 reads (35%) | catalogued as COSV65662229; called by muse, mutect2, varscan2
- FEM1B | c.1495G>A p.D499N | Missense Mutation (SNP) | VAF 58/216 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV100183766, COSV60988396; called by muse, mutect2, varscan2
- FNBP4 | c.476A>T p.Q159L | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV55448186; called by muse, mutect2, varscan2
- GABRA2 | c.594G>T p.W198C | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62914485; called by muse, mutect2
- GALNT8 | c.659A>G p.D220G | Missense Mutation (SNP) | VAF 50/120 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52897016; called by muse, mutect2, varscan2
- GCSAML | c.188G>C p.G63A | Missense Mutation (SNP) | VAF 50/229 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.59); catalogued as COSV63577685; called by muse, mutect2, varscan2
- GIMAP7 | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 7/79 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57959285; called by muse, mutect2, varscan2
- GMDS | c.539-1G>T p.X180_splice | Splice Site (SNP) | VAF 12/55 reads (22%) | catalogued as COSV66433302; called by muse, mutect2
- GNAI1 | c.304G>C p.D102H | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.587); catalogued as COSV63522670; called by muse, mutect2, varscan2
- GON4L | c.5604G>T p.R1868S | Missense Mutation (SNP) | VAF 29/318 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.115); catalogued as COSV55192776; called by muse, mutect2
- GPAA1 | c.898G>T p.G300C | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60155635, COSV60155723; called by muse, mutect2, varscan2
- GRM1 | c.806G>C p.S269T | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.192); catalogued as COSV51137842; called by muse, mutect2, varscan2
- GRM2 | c.1307A>T p.D436V | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.309); catalogued as COSV56584572; called by muse, mutect2, varscan2
- GRM8 | c.2555G>T p.R852L | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.326); catalogued as COSV100281794, COSV58822935; called by muse, mutect2, varscan2
- GTF3C3 | c.2255C>T p.A752V | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748640443, COSV55831928; called by muse, mutect2, varscan2
- GUCY1A2 | c.1700C>A p.T567K | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56485094; called by muse, mutect2, varscan2
- GUCY2C | c.112A>C p.S38R | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.401); catalogued as COSV53789517; called by muse, mutect2, varscan2
- HEATR5A | c.1676G>T p.G559V | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1291453108, COSV101119800; called by muse, mutect2, varscan2
- HELZ | c.4912A>T p.S1638C | Missense Mutation (SNP) | VAF 15/176 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.436); catalogued as COSV62378077; called by muse, mutect2
- HMCN1 | c.9965C>A p.T3322N | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.997); catalogued as COSV54896241; called by muse, mutect2
- HSP90AB1 | c.1024G>C p.D342H | Missense Mutation (SNP) | VAF 22/184 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100807077, COSV62334341; called by muse, mutect2, varscan2
- HSPA12A | c.1699G>A p.V567I | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.05); catalogued as rs146839286; called by muse, mutect2, varscan2
- IGSF11 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 14/55 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV61169001; called by muse, mutect2, varscan2
- INO80E | c.407C>T p.S136F | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV54229777; called by muse, mutect2
- INTS10 | c.985A>T p.I329L | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV67604089; called by muse, mutect2, varscan2
- ITGAD | c.238C>G p.H80D | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.041); catalogued as COSV66757776; called by muse, mutect2
- KCNA1 | c.599del p.G200Afs*55 | Frame Shift Del (DEL) | VAF 7/72 reads (10%) | catalogued as COSV101230237; called by mutect2, pindel
- KCNU1 | c.3313A>G p.I1105V | Missense Mutation (SNP) | VAF 21/197 reads (11%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV67755154; called by muse, mutect2, varscan2
- KIAA1549L | c.1039T>G p.F347V (on ENST00000321505; = p.F644V on NM_012194.3) | Missense Mutation (SNP) | VAF 50/216 reads (23%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV55772782; called by muse, mutect2, varscan2
- KIF21B | c.1807G>T p.E603* | Nonsense Mutation (SNP) | VAF 46/199 reads (23%) | catalogued as COSV59753212, COSV59756817; called by muse, mutect2, varscan2
- KIF21B | c.1564G>A p.A522T | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs774020793, COSV59756839, COSV59763514; called by muse, mutect2, varscan2
- KIF2B | c.391C>A p.L131M | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.519); catalogued as COSV52129831, COSV52133600; called by muse, mutect2, varscan2
- KIR3DL1 | c.454C>A p.H152N | Missense Mutation (SNP) | VAF 20/239 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.025); catalogued as COSV58490160; called by muse, mutect2
- KLHL1 | c.223T>A p.S75T | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.006); catalogued as COSV64771490; called by muse, mutect2, varscan2
- KRT14 | c.1197G>T p.K399N | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.123); catalogued as COSV51421118; called by muse, mutect2, varscan2
- LAMA4 | c.1197C>A p.N399K (on ENST00000230538 / NM_001105206.3; = p.N392K on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT tolerated (0.92); PolyPhen benign (0.088); catalogued as rs376451323, COSV100038037; called by muse, mutect2, varscan2
- LAMC3 | c.532T>C p.Y178H | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.152); catalogued as COSV63090660; called by muse, mutect2, varscan2
- LILRB1 | c.1360G>T p.V454L (on ENST00000427581; = p.V418L on NM_006669.6) | Missense Mutation (SNP) | VAF 56/220 reads (25%) | SIFT tolerated (0.64); PolyPhen benign (0.042); catalogued as rs772220693, COSV61117632; called by muse, varscan2
- LRP1B | c.11285G>T p.C3762F | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67211964; called by muse, mutect2, varscan2
- LRRC32 | c.437G>T p.G146V | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.105); catalogued as COSV52632754; called by muse, mutect2, varscan2
- LRRC55 | c.559G>T p.G187W | Missense Mutation (SNP) | VAF 39/206 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV73006492; called by muse, mutect2, varscan2
- LRRFIP1 | c.322C>A p.L108M | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55251405; called by muse, mutect2, varscan2
- LTBP1 | c.2106C>A p.C702* (on ENST00000404816 / NM_206943.4; = p.C376* on NM_000627.4) | Nonsense Mutation (SNP) | VAF 56/212 reads (26%) | catalogued as COSV63185474; called by muse, mutect2, varscan2
- MAP1B | c.6979T>A p.S2327T | Missense Mutation (SNP) | VAF 15/220 reads (7%) | SIFT tolerated (0.7); PolyPhen benign (0.01); catalogued as COSV57098156; called by muse, mutect2
- MEGF6 | c.2459G>T p.G820V | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53889161; called by muse, mutect2, varscan2
- MICAL1 | c.589C>G p.Q197E | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62193231, COSV99068264; called by muse, mutect2, varscan2
- MIS18A | c.213G>T p.E71D | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.04); catalogued as COSV99267017; called by muse, mutect2, varscan2
- MKRN3 | c.394G>T p.V132F | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV58808348, COSV58809659; called by muse, mutect2, varscan2
- MMP16 | c.1123G>T p.D375Y | Missense Mutation (SNP) | VAF 24/270 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.887); catalogued as COSV54188081, COSV99688787; called by muse, mutect2
- MMP16 | c.1122G>T p.M374I | Missense Mutation (SNP) | VAF 26/275 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV99687127; called by muse, mutect2
- MOGAT2 | c.403A>T p.I135F | Missense Mutation (SNP) | VAF 66/262 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.044); catalogued as COSV99549471; called by muse, mutect2, varscan2
- MORC1 | c.1658A>G p.E553G | Missense Mutation (SNP) | VAF 54/190 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV51718970; called by muse, mutect2, varscan2
- MRGPRX4 | c.257G>T p.R86L | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV58590422; called by muse, mutect2, varscan2
- MRPS11 | c.67A>T p.R23W | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.293); catalogued as COSV56899836; called by muse, mutect2, varscan2
- MRPS7 | c.229G>C p.A77P | Missense Mutation (SNP) | VAF 24/316 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.585); catalogued as COSV55453382; called by muse, mutect2
- MTR | c.160C>T p.Q54* | Nonsense Mutation (SNP) | VAF 57/160 reads (36%) | catalogued as COSV63967838; called by muse, mutect2, varscan2
- MTR | c.427G>T p.A143S | Missense Mutation (SNP) | VAF 38/234 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs1179107463, COSV63967841; called by muse, mutect2, varscan2
- MXRA5 | c.1751C>A p.T584K | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.086); catalogued as COSV54233161; called by muse, varscan2
- MYH13 | c.4112A>T p.E1371V | Missense Mutation (SNP) | VAF 97/386 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52826894; called by muse, mutect2, varscan2
- MYH7 | c.2462T>C p.F821S | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs397516148, COSV62518707; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH8 | c.188C>T p.T63I | Missense Mutation (SNP) | VAF 103/414 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.196); catalogued as COSV67964056; called by muse, mutect2, varscan2
- MYO3B | c.1018G>T p.E340* | Nonsense Mutation (SNP) | VAF 22/95 reads (23%) | catalogued as COSV58701858; called by muse, mutect2, varscan2
- MYOZ2 | c.100A>C p.K34Q | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV61084721; called by muse, mutect2, varscan2
- NCOR2 | c.2144A>T p.E715V | Missense Mutation (SNP) | VAF 24/258 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62297244; called by muse, mutect2
- NDNF | c.958A>G p.N320D | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV65633276; called by muse, mutect2, varscan2
- NDUFAF6 | c.248C>G p.S83C | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.05); catalogued as COSV54408226; called by muse, mutect2
- NDUFB8 | c.238G>T p.D80Y | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV54511758; called by muse, mutect2
- NEK7 | c.432G>T p.Q144H | Missense Mutation (SNP) | VAF 10/270 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV66314891; called by muse, mutect2
- NELL2 | c.2321T>A p.L774Q | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.276); catalogued as COSV61573683; called by muse, mutect2, varscan2
- NLRP1 | c.3974T>C p.V1325A (on ENST00000572272 / NM_033004.4; = p.V1281A on NM_014922.5) | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.944); catalogued as rs199687052, COSV52565006; called by muse, mutect2, varscan2
- NLRP2 | c.1052C>T p.P351L | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762141241, COSV54754568; called by muse, mutect2
- NNT | c.2527G>T p.G843C | Missense Mutation (SNP) | VAF 50/202 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52924532; called by muse, mutect2, varscan2
- NOBOX | c.944G>T p.R315L | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56194007; called by muse, mutect2, varscan2
- NPAS4 | c.1634C>A p.P545H | Missense Mutation (SNP) | VAF 129/393 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV60650150, COSV60651138; called by muse, mutect2, varscan2
- NSUN2 | c.2257G>C p.D753H | Missense Mutation (SNP) | VAF 10/214 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.201); catalogued as COSV52954023; called by muse, mutect2
- NXPH2 | c.692T>A p.I231N | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55642139; called by muse, mutect2, varscan2
- OR10Z1 | c.167A>T p.H56L | Missense Mutation (SNP) | VAF 93/467 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV63524612; called by muse, mutect2, varscan2
- OR13C9 | c.179A>T p.Y60F | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); catalogued as COSV52241740; called by muse, mutect2, varscan2
- OR14A16 | c.115G>T p.G39W | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV62926564; called by muse, mutect2, varscan2
- OR2D2 | c.523G>T p.A175S | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.054); catalogued as COSV55056968; called by muse, mutect2, varscan2
- OR2G2 | c.377A>C p.Y126S | Missense Mutation (SNP) | VAF 126/409 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100190057, COSV60740347, COSV60742203; called by muse, mutect2, varscan2
- OR4C3 | c.431G>A p.G144E | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.772); catalogued as rs758744609, COSV60585450; called by muse, mutect2, varscan2
- OR51E2 | c.320C>A p.S107* | Nonsense Mutation (SNP) | VAF 29/64 reads (45%) | catalogued as COSV67807385; called by muse, mutect2, varscan2
- OR51S1 | c.433A>T p.T145S | Missense Mutation (SNP) | VAF 46/184 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.763); catalogued as COSV59058206; called by muse, mutect2, varscan2
- OR52N4 | c.297C>G p.C99W | Missense Mutation (SNP) | VAF 9/141 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57890937; called by muse, mutect2
- OR5L1 | c.172C>A p.P58T | Missense Mutation (SNP) | VAF 93/372 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1363294712, COSV61732870, COSV61733662; called by muse, varscan2
- OR5L1 | c.617A>G p.N206S | Missense Mutation (SNP) | VAF 73/253 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.119); catalogued as COSV61733667; called by muse, mutect2, varscan2
- OTUD7B | c.1087G>T p.V363L | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64916035; called by muse, mutect2, varscan2
- PADI2 | c.1777G>A p.V593M | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs753825782, COSV64953728; called by muse, mutect2, varscan2
- PAPPA2 | c.4490C>G p.A1497G | Missense Mutation (SNP) | VAF 31/196 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV100867765; called by muse, mutect2, varscan2
- PCDH11X | c.2773C>A p.P925T | Missense Mutation (SNP) | VAF 28/170 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV53461206; called by muse, mutect2, varscan2
- PCDH15 | c.4600A>T p.K1534* | Nonsense Mutation (SNP) | VAF 59/205 reads (29%) | catalogued as COSV64682835, COSV64690443; called by muse, mutect2, varscan2
- PCDHA2 | c.1787C>A p.A596E | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV65366625; called by muse, mutect2, varscan2
- PCDHA4 | c.1672G>A p.E558K | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.926); catalogued as rs267600385, COSV63540193; called by muse, mutect2
- PCDHB12 | c.2324T>A p.L775Q | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.003); catalogued as COSV53396129; called by muse, mutect2, varscan2
- PCDHGA8 | c.1031G>T p.R344I | Missense Mutation (SNP) | VAF 60/255 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.005); catalogued as COSV53937341; called by muse, mutect2, varscan2
- PCDHGA9 | c.538C>A p.L180M | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV53937349; called by muse, mutect2, varscan2
- PCSK6 | c.1384G>T p.D462Y | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369879412, COSV59340352; called by muse, mutect2, varscan2
- PDGFRB | c.3034G>T p.V1012L | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.675); catalogued as rs757545741, COSV53833936, COSV53844019; called by muse, mutect2, varscan2
- PIGG | c.677G>T p.G226V | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56317713; called by muse, mutect2, varscan2
- PLAC1 | c.271A>C p.M91L | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as COSV63655669; called by muse, mutect2
- PLCH1 | c.2350G>A p.D784N (on ENST00000340059 / NM_001130960.2; = p.D796N on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs1319169735, COSV58194968; called by muse, mutect2, varscan2
- PLEKHA7 | c.2889G>T p.R963S | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100261871; called by muse, mutect2, varscan2
- PLEKHA7 | c.2888G>T p.R963M | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100261885; called by muse, mutect2, varscan2
- PLOD2 | c.2107C>T p.R703* | Nonsense Mutation (SNP) | VAF 4/34 reads (12%) | catalogued as COSV51464288; called by muse, mutect2
- POC5 | c.1180G>T p.G394* (on ENST00000428202 / NM_001099271.2; = p.G369* on NM_152408.2) | Nonsense Mutation (SNP) | VAF 40/155 reads (26%) | catalogued as COSV66842156; called by muse, mutect2, varscan2
- PRAMEF6 | c.420G>C p.R140S | Missense Mutation (SNP) | VAF 50/457 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs150586267, COSV61910137; called by muse, varscan2
- PREB | c.904G>A p.V302I | Missense Mutation (SNP) | VAF 22/293 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV53205834; called by muse, mutect2
- PREX1 | c.643G>A p.G215S | Missense Mutation (SNP) | VAF 68/302 reads (23%) | SIFT tolerated (0.6); PolyPhen benign (0.025); catalogued as rs776160255, COSV64251207; called by muse, mutect2, varscan2
- PRKN | c.474G>T p.Q158H | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.847); catalogued as COSV58221957; called by muse, mutect2, varscan2
- PSD3 | c.811G>T p.E271* | Nonsense Mutation (SNP) | VAF 24/57 reads (42%) | catalogued as COSV58967595; called by muse, mutect2, varscan2
- PSD4 | c.1197G>T p.W399C | Missense Mutation (SNP) | VAF 50/239 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as rs974690441, COSV55526434; called by muse, mutect2, varscan2
- PSG5 | c.618T>A p.S206R | Missense Mutation (SNP) | VAF 58/290 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.026); catalogued as COSV61654094; called by muse, mutect2, varscan2
- PTCD1 | c.172G>T p.E58* | Nonsense Mutation (SNP) | VAF 7/18 reads (39%) | catalogued as COSV52857366; called by muse, mutect2, varscan2
- PTPRT | c.1611C>G p.S537R | Missense Mutation (SNP) | VAF 48/156 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.232); catalogued as COSV61977689, COSV62024852; called by muse, mutect2, varscan2
- PXDC1 | c.579-1G>C p.X193_splice | Splice Site (SNP) | VAF 10/59 reads (17%) | catalogued as COSV100977195, COSV100977214; called by muse, mutect2, varscan2
- PXDN | c.2361C>A p.Y787* | Nonsense Mutation (SNP) | VAF 33/125 reads (26%) | catalogued as COSV53232589; called by muse, mutect2, varscan2
- RALYL | c.101A>G p.K34R | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV72820122; called by muse, mutect2, varscan2
- RAPGEF2 | c.2406G>T p.K802N | Missense Mutation (SNP) | VAF 31/182 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52424703; called by muse, mutect2, varscan2
- RPTN | c.988C>A p.H330N | Missense Mutation (SNP) | VAF 384/1571 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.205); catalogued as COSV60167041, COSV60167113; called by muse, mutect2, varscan2
- RTL9 | c.3944A>T p.K1315M | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.975); catalogued as COSV71825519; called by muse, mutect2, varscan2
- RTP2 | c.499C>A p.P167T | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV64078959; called by muse, mutect2, varscan2
- RYR2 | c.3113T>C p.L1038P | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV100769214, COSV63721056; called by muse, mutect2
- SAMSN1 | c.404C>A p.S135* | Nonsense Mutation (SNP) | VAF 82/288 reads (28%) | catalogued as COSV53470737; called by muse, mutect2, varscan2
- SCN5A | c.3523C>T p.R1175C (on ENST00000333535 / NM_198056.3; = p.R1174C on NM_000335.5) | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.943); catalogued as rs199473200, HM0640, COSV61122530; ClinVar: not provided; called by muse, mutect2, varscan2
- SDK1 | c.5906G>T p.R1969L | Missense Mutation (SNP) | VAF 60/180 reads (33%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.679); catalogued as COSV67356570, COSV67366479; called by muse, mutect2, varscan2
- SEMA5A | c.933G>C p.V311= | Splice Region (SNP) | VAF 26/164 reads (16%) | catalogued as COSV66791265, COSV66804703; called by muse, mutect2, varscan2
- SEMA6D | c.1088C>A p.P363Q | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60376309; called by muse, mutect2, varscan2
- SERPINE3 | c.409A>T p.S137C | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.08); catalogued as COSV68545257; called by muse, mutect2, varscan2
- SF1 | c.610C>T p.H204Y | Missense Mutation (SNP) | VAF 93/280 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57113512; called by muse, mutect2, varscan2
- SIGLEC12 | c.1603C>A p.P535T (on ENST00000291707 / NM_053003.4; = p.P417T on NM_033329.2) | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV52461112; called by muse, mutect2, varscan2
- SIGLEC15 | c.952C>A p.P318T | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); catalogued as COSV67181082; called by muse, mutect2, varscan2
- SIGLEC8 | c.469C>A p.P157T | Missense Mutation (SNP) | VAF 24/182 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV58473460; called by muse, mutect2, varscan2
- SLC15A2 | c.1394A>T p.H465L | Missense Mutation (SNP) | VAF 22/251 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0.05); catalogued as COSV55197512, COSV55199462; called by muse, mutect2
- SLC17A1 | c.529+2T>A p.X177_splice | Splice Site (SNP) | VAF 30/125 reads (24%) | catalogued as COSV55078608; called by muse, mutect2, varscan2
- SLC35G3 | c.592C>A p.L198M | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.021); catalogued as COSV52011027; called by muse, mutect2, varscan2
- SLC38A7 | c.1081G>T p.E361* | Nonsense Mutation (SNP) | VAF 14/126 reads (11%) | catalogued as COSV99543719; called by muse, mutect2, varscan2
- SLC4A4 | c.769A>T p.S257C (on ENST00000264485 / NM_001098484.3; = p.S213C on NM_003759.4) | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV52622917, COSV52629364; called by muse, mutect2, varscan2
- SLC6A5 | c.814T>C p.C272R | Missense Mutation (SNP) | VAF 15/463 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV54225944; called by muse, mutect2
- SLC7A8 | c.1413C>A p.H471Q | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as COSV57553733, COSV57553882; called by muse, mutect2, varscan2
- SLCO1B3 | c.655G>T p.G219C | Missense Mutation (SNP) | VAF 45/161 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53936182; called by muse, mutect2, varscan2
- SLIT3 | c.3787G>A p.G1263R | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.821); catalogued as COSV60605816; called by muse, mutect2, varscan2
- SMAD3 | c.1267A>C p.S423R | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as CM145137, COSV59283287, COSV59288829; called by muse, mutect2, varscan2
- SMARCA2 | c.112G>T p.G38C | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.735); catalogued as rs768632343, COSV100570653; called by muse, mutect2, varscan2
- SMARCA2 | c.113G>T p.G38V | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.522); catalogued as rs774085434, COSV100570656; called by muse, mutect2, varscan2
- SNX29 | c.1069G>T p.V357L | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as rs759615730, COSV60057796, COSV60063078; called by muse, mutect2, varscan2
- SOCS5 | c.976G>T p.E326* | Nonsense Mutation (SNP) | VAF 31/131 reads (24%) | catalogued as COSV60604483; called by muse, mutect2, varscan2
- SORCS2 | c.2524T>G p.Y842D | Missense Mutation (SNP) | VAF 56/190 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61168493; called by muse, mutect2, varscan2
- SORT1 | c.663G>A p.M221I | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV56665934; called by muse, mutect2, varscan2
- SPATA7 | c.997A>T p.K333* | Nonsense Mutation (SNP) | VAF 18/75 reads (24%) | catalogued as COSV50416807; called by muse, mutect2
- SPATA7 | c.999G>T p.K333N | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV50416825; called by muse, mutect2
- SPEG | c.1079C>A p.S360* | Nonsense Mutation (SNP) | VAF 7/51 reads (14%) | catalogued as COSV56667786; called by muse, mutect2, varscan2
- SPTA1 | c.2374C>G p.L792V | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT tolerated (0.53); PolyPhen benign (0.043); catalogued as COSV63752319; called by muse, mutect2
- SRCAP | c.4754C>A p.T1585N | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV52671703; called by muse, mutect2, varscan2
- SSTR4 | c.1094C>T p.P365L | Missense Mutation (SNP) | VAF 45/152 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV54797929; called by muse, mutect2, varscan2
- STK11 | c.407T>A p.M136K | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as CM011963, CM1312244, COSV100480034; called by muse, mutect2, varscan2
- STK11 | c.408G>T p.M136I | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV100480040; called by muse, mutect2, varscan2
- STOM | c.454A>T p.R152W | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54418103; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2534T>C p.V845A | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100561685; called by muse, mutect2, varscan2
- STOX1 | c.2246G>T p.R749L | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV53813062, COSV53814542; called by muse, mutect2, varscan2
- STX3 | c.223G>C p.D75H | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.811); catalogued as COSV55697402; called by muse, mutect2, varscan2
- STXBP5L | c.1106C>G p.P369R | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.714); catalogued as COSV56511347; called by muse, mutect2, varscan2
- SULF2 | c.1171G>C p.D391H | Missense Mutation (SNP) | VAF 28/568 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.975); catalogued as COSV63415619; called by muse, mutect2
- SVEP1 | c.9503G>T p.R3168L | Missense Mutation (SNP) | VAF 91/437 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs779233113, COSV52836925, COSV52838646; called by muse, mutect2, varscan2
- TAB1 | c.998G>C p.R333P | Missense Mutation (SNP) | VAF 33/165 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs760365693, COSV53370907; called by muse, mutect2, varscan2
- TAF1L | c.5241del p.E1748Rfs*44 | Frame Shift Del (DEL) | VAF 26/174 reads (15%) | catalogued as COSV54259084; called by mutect2, pindel, varscan2
- TAS1R2 | c.1972G>A p.A658T | Missense Mutation (SNP) | VAF 27/193 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as rs145202761; called by muse, mutect2, varscan2
- TBC1D3F | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 57/407 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as rs1398394042; called by muse, mutect2, varscan2
- TBX3 | c.613C>A p.H205N | Missense Mutation (SNP) | VAF 53/235 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV57471059; called by muse, mutect2, varscan2
- TEAD4 | c.451G>T p.A151S | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.66); PolyPhen benign (0.098); catalogued as rs1290903018, COSV63280843; called by muse, mutect2, varscan2
- TEX47 | c.79C>T p.R27C | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769670567, COSV51878484; called by muse, mutect2, varscan2
- TLE3 | c.1459del p.E487Rfs*6 | Frame Shift Del (DEL) | VAF 57/173 reads (33%) | catalogued as COSV100450229; called by mutect2, pindel, varscan2
- TMEM106A | c.704A>T p.E235V | Missense Mutation (SNP) | VAF 116/391 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV59045262; called by muse, mutect2, varscan2
- TMTC3 | c.1622A>C p.N541T | Missense Mutation (SNP) | VAF 43/147 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.588); catalogued as COSV57123717; called by muse, mutect2, varscan2
- TMX2 | c.863C>T p.S288L | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV53554134; called by muse, mutect2, varscan2
- TNRC18 | c.3902G>T p.G1301V | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.231); catalogued as COSV68165071; called by muse, mutect2, varscan2
- TPH2 | c.440-1G>T p.X147_splice | Splice Site (SNP) | VAF 45/144 reads (31%) | catalogued as COSV61591743; called by muse, mutect2, varscan2
- TPX2 | c.158G>T p.G53V | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.38); catalogued as COSV55919186; called by muse, mutect2, varscan2
- TRIM56 | c.397G>T p.D133Y | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV60157234; called by muse, mutect2, varscan2
- TRIML1 | c.994G>C p.G332R | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1438861024, COSV60194127; called by muse, mutect2, varscan2
- TTC26 | c.471G>T p.L157F | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100570942; called by muse, mutect2, varscan2
- TTC26 | c.472G>T p.A158S | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100570944; called by muse, mutect2, varscan2
- TTI1 | c.1027G>T p.E343* | Nonsense Mutation (SNP) | VAF 33/134 reads (25%) | catalogued as COSV65061466; called by muse, mutect2, varscan2
- TTN | c.35423C>G p.P11808R (on ENST00000591111; = p.P10881R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/30 reads (30%) | PolyPhen probably damaging (0.998); catalogued as COSV60017641; called by muse, mutect2, varscan2
- TTN | c.24627C>A p.Y8209* (on ENST00000591111; = p.Y7282* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 7/57 reads (12%) | catalogued as rs746964059, COSV100603517; called by muse, mutect2, varscan2
- UBR1 | c.238G>A p.G80R | Missense Mutation (SNP) | VAF 44/149 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.046); catalogued as COSV51929204; called by muse, mutect2, varscan2
- UNC5A | c.71-1G>C p.X24_splice | Splice Site (SNP) | VAF 8/31 reads (26%) | catalogued as COSV56167455; called by muse, mutect2
- UNC5C | c.830G>T p.G277V | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71659203; called by muse, mutect2, varscan2
- UPB1 | c.1003G>T p.D335Y | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58113306; called by muse, mutect2, varscan2
- VPS13A | c.9427A>G p.R3143G | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV64328847; called by muse, mutect2, varscan2
- VPS13C | c.1009C>T p.Q337* (on ENST00000644861 / NM_020821.3; = p.Q294* on NM_017684.5) | Nonsense Mutation (SNP) | VAF 66/176 reads (38%) | catalogued as COSV51163861, COSV99827348; called by muse, mutect2, varscan2
- VRTN | c.650C>A p.T217K | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV56440734; called by muse, mutect2, varscan2
- VSIR | c.445G>T p.V149L | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.033); catalogued as COSV56460746; called by muse, mutect2, varscan2
- WRN | c.2492C>T p.A831V | Missense Mutation (SNP) | VAF 79/250 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV53296259; called by muse, mutect2, varscan2
- WTAP | c.470T>C p.L157S | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61610033; called by muse, mutect2, varscan2
- XPNPEP1 | c.691A>T p.K231* | Nonsense Mutation (SNP) | VAF 14/66 reads (21%) | catalogued as COSV59167846; called by muse, mutect2, varscan2
- ZBTB39 | c.70C>T p.R24W | Missense Mutation (SNP) | VAF 76/275 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1402826656, COSV55629191; called by muse, mutect2, varscan2
- ZBTB41 | c.1012G>T p.G338C | Missense Mutation (SNP) | VAF 15/168 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.122); catalogued as COSV66359083; called by muse, mutect2, varscan2
- ZFHX4 | c.8668G>T p.D2890Y | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.961); catalogued as COSV50726025; called by muse, mutect2, varscan2
- ZFHX4 | c.9347C>G p.S3116C | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV50726488, COSV50893972, COSV51488364; called by muse, mutect2, varscan2
- ZFYVE28 | c.1337G>A p.G446E | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.003); catalogued as COSV52110507, COSV52113640; called by muse, mutect2, varscan2
- ZFYVE9 | c.4114C>A p.Q1372K | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.098); catalogued as COSV55093291; called by muse, mutect2, varscan2
- ZG16B | c.470C>A p.P157H | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV66525832, COSV66525942; called by muse, mutect2, varscan2
- ZNF148 | c.1763G>T p.G588V | Missense Mutation (SNP) | VAF 48/159 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV62304325; called by muse, mutect2, varscan2
- ZNF184 | c.281C>T p.P94L | Missense Mutation (SNP) | VAF 62/152 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0.031); catalogued as rs766911233, COSV53004144, COSV53005384; called by muse, mutect2, varscan2
- ZNF292 | c.1361G>T p.R454L | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60536476; called by muse, mutect2, varscan2
- ZNF335 | c.987G>T p.E329D | Missense Mutation (SNP) | VAF 40/158 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.039); catalogued as rs369786901, COSV59817483; called by muse, mutect2, varscan2
- ZNF423 | c.2723T>A p.L908Q (on ENST00000563137 / NM_001379286.1; = p.L900Q on NM_015069.4) | Missense Mutation (SNP) | VAF 36/146 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as COSV52186285; called by muse, varscan2
- ZNF423 | c.2669C>T p.S890L (on ENST00000563137 / NM_001379286.1; = p.S882L on NM_015069.4) | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as rs777639594, COSV52186306; ClinVar: uncertain significance; called by muse, varscan2
- ZNF445 | c.2386G>C p.G796R | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV68538794; called by muse, mutect2
- ZNF559 | c.200A>C p.Q67P | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV57835525; called by muse, mutect2, varscan2
- ZNF585B | c.2246G>T p.G749V | Missense Mutation (SNP) | VAF 52/220 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV57215265; called by muse, mutect2, varscan2
- ZNF676 | c.1794T>A p.C598* (on ENST00000650058; = p.C566* on NM_001001411.3) | Nonsense Mutation (SNP) | VAF 6/72 reads (8%) | catalogued as COSV68092937; called by muse, mutect2
- ZNF768 | c.608G>C p.G203A | Missense Mutation (SNP) | VAF 15/166 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV53223723; called by muse, mutect2, varscan2
- ZNF835 | c.202G>T p.A68S | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV101606309; called by muse, mutect2, varscan2
- ZNF862 | c.1493A>T p.D498V | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56223757; called by muse, mutect2, varscan2
- ZSCAN25 | c.1447G>T p.E483* | Nonsense Mutation (SNP) | VAF 12/117 reads (10%) | catalogued as COSV53552875; called by muse, mutect2, varscan2
- ARV1 | c.575dup p.L192Ffs*11 | Frame Shift Ins (INS) | VAF 66/207 reads (32%) | called by mutect2, pindel, varscan2
- C1GALT1 | c.29dup p.L10Ffs*19 | Frame Shift Ins (INS) | VAF 19/90 reads (21%) | called by mutect2, pindel, varscan2
- CAPN10 | c.1189del p.R397Gfs*31 | Frame Shift Del (DEL) | VAF 26/113 reads (23%) | called by mutect2, pindel, varscan2
- KLHL32 | c.347del p.L116Qfs*24 | Frame Shift Del (DEL) | VAF 10/83 reads (12%) | called by mutect2, pindel, varscan2
- MAGEB6B | c.832G>T p.G278C | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MANEA | c.1137del p.K380Sfs*7 | Frame Shift Del (DEL) | VAF 33/170 reads (19%) | called by mutect2, pindel, varscan2
- PCDHA1 | c.786del p.T263Hfs*2 | Frame Shift Del (DEL) | VAF 34/129 reads (26%) | called by mutect2, pindel, varscan2
- PRSS55 | c.74del p.P25Qfs*8 | Frame Shift Del (DEL) | VAF 15/46 reads (33%) | called by mutect2, pindel, varscan2
- SRRM3 | c.263_264dup p.G89Wfs*8 | Frame Shift Ins (INS) | VAF 10/51 reads (20%) | called by mutect2, pindel, varscan2
- TPTE | c.729A>T p.T243= (on ENST00000618007 / NM_199261.4; = p.T225= on NM_199259.4) | Splice Region (SNP) | VAF 101/782 reads (13%) | called by muse, mutect2
- TRIM48 | c.124del p.V42Sfs*3 | Frame Shift Del (DEL) | VAF 30/282 reads (11%) | called by pindel, varscan2
- UCHL5 | c.325del p.E109Rfs*17 | Frame Shift Del (DEL) | VAF 11/63 reads (17%) | called by mutect2, pindel, varscan2
- WWTR1 | c.1079del p.F360Sfs*12 | Frame Shift Del (DEL) | VAF 42/237 reads (18%) | called by mutect2, pindel, varscan2
- ZIM2 | c.1533dup p.H512Tfs*12 | Frame Shift Ins (INS) | VAF 22/102 reads (22%) | called by mutect2, pindel, varscan2
- ABL1 | c.612G>C p.T204= | Silent (SNP) | VAF 43/178 reads (24%) | catalogued as COSV59330460; called by muse, mutect2, varscan2
- ADAM7 | c.2124C>A p.T708= | Silent (SNP) | VAF 42/155 reads (27%) | catalogued as rs1480596463, COSV51539115; called by muse, mutect2, varscan2
- ADCY2 | c.2553G>C p.L851= | Silent (SNP) | VAF 11/78 reads (14%) | catalogued as COSV57870012, COSV57876700; called by muse, mutect2, varscan2
- AHNAK | c.14895C>T p.I4965= | Silent (SNP) | VAF 18/95 reads (19%) | catalogued as rs537813230, COSV57203342; called by muse, mutect2, varscan2
- AMELY | c.498C>A p.P166= (on ENST00000383036 / NM_001364814.1; = p.P152= on NM_001143.1) | Silent (SNP) | VAF 19/29 reads (66%) | catalogued as COSV53095728; called by muse, mutect2, varscan2
- ANO3 | c.2580C>T p.C860= | Silent (SNP) | VAF 20/126 reads (16%) | catalogued as COSV56789769; called by muse, mutect2, varscan2
- AP001781.2 | c.483G>T p.V161= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as COSV52788249; called by muse, mutect2, varscan2
- ARID2 | c.4794A>T p.S1598= | Silent (SNP) | VAF 10/95 reads (11%) | catalogued as COSV57602452; called by muse, mutect2, varscan2
- CARS1 | c.1665G>A p.L555= | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as COSV53453607; called by muse, mutect2, varscan2
- CCDC120 | c.966C>T p.G322= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as COSV64480889; called by muse, mutect2, varscan2
- CDH20 | c.1770G>T p.L590= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as COSV53008877; called by muse, mutect2, varscan2
- CDH6 | c.981G>T p.G327= | Silent (SNP) | VAF 26/117 reads (22%) | catalogued as COSV54068777, COSV99418456; called by muse, mutect2, varscan2
- CENPN | c.540A>T p.T180= | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as COSV55142244; called by muse, mutect2, varscan2
- CEP250 | c.2851C>T p.L951= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV61169751; called by muse, mutect2
- CHORDC1 | c.750A>T p.S250= | Silent (SNP) | VAF 20/138 reads (14%) | catalogued as COSV57705907; called by muse, mutect2, varscan2
- CHRNA4 | c.156C>A p.S52= | Silent (SNP) | VAF 27/117 reads (23%) | catalogued as COSV64717621; called by muse, mutect2, varscan2
- CLCA1 | c.2187C>T p.S729= | Silent (SNP) | VAF 36/127 reads (28%) | catalogued as COSV52327462; called by muse, mutect2, varscan2
- CNMD | c.177C>A p.I59= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV65032914; called by muse, mutect2, varscan2
- CNTNAP5 | c.558A>T p.R186= | Silent (SNP) | VAF 38/170 reads (22%) | catalogued as COSV70483904; called by muse, mutect2, varscan2
- COL14A1 | c.5037C>T p.F1679= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as rs767814150, COSV52853162; called by muse, mutect2
- COL5A1 | c.3564C>T p.I1188= | Silent (SNP) | VAF 67/268 reads (25%) | catalogued as rs766961124, COSV65668398; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- CSMD1 | c.6144G>C p.T2048= (on ENST00000520002; = p.T2047= on NM_033225.6) | Silent (SNP) | VAF 9/77 reads (12%) | catalogued as COSV59280209, COSV59291989, COSV59316091; called by muse, mutect2, varscan2
- CTTNBP2 | c.1113C>A p.P371= | Silent (SNP) | VAF 22/87 reads (25%) | catalogued as COSV50398106; called by muse, mutect2, varscan2
- DGKI | c.3126C>T p.D1042= | Silent (SNP) | VAF 26/84 reads (31%) | catalogued as COSV55947573, COSV55974655; called by muse, mutect2, varscan2
- DIDO1 | c.5757C>A p.P1919= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as COSV56620809; called by muse, varscan2
- DNAH9 | c.5781C>T p.I1927= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as COSV52347118; called by muse, mutect2, varscan2
- DZIP1 | c.2487C>A p.A829= (on ENST00000347108; = p.A810= on NM_014934.5) | Silent (SNP) | VAF 12/118 reads (10%) | catalogued as COSV61265453; called by muse, mutect2, varscan2
- ENOPH1 | c.693G>T p.V231= | Silent (SNP) | VAF 20/95 reads (21%) | catalogued as COSV99908621, COSV99908765; called by muse, mutect2, varscan2
- FBN2 | c.8688A>T p.L2896= | Silent (SNP) | VAF 37/99 reads (37%) | catalogued as COSV52509458; called by muse, mutect2, varscan2
- FZD1 | c.1656C>T p.I552= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as rs1373346273, COSV55310156; called by muse, mutect2, varscan2
- GALNT8 | c.114G>T p.T38= | Silent (SNP) | VAF 37/106 reads (35%) | catalogued as COSV52897006; called by muse, mutect2, varscan2
- GLCCI1 | c.1317G>A p.S439= | Silent (SNP) | VAF 39/200 reads (20%) | catalogued as rs774016200, COSV56201492; called by muse, mutect2, varscan2
- GPR107 | c.522A>T p.T174= | Silent (SNP) | VAF 4/59 reads (7%) | catalogued as COSV61279080; called by muse, mutect2
- HAND1 | c.84C>G p.L28= | Silent (SNP) | VAF 14/227 reads (6%) | catalogued as COSV50562539; called by muse, mutect2
- HGF | c.285A>G p.Q95= | Silent (SNP) | VAF 18/98 reads (18%) | catalogued as rs778319588, COSV55948563, COSV55948810, COSV55951471; called by muse, mutect2, varscan2
- ICE1 | c.1335C>T p.F445= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as rs768392308, COSV56823382; called by muse, mutect2, varscan2
- IGKV3D-11 | c.216C>T p.S72= | Silent (SNP) | VAF 17/164 reads (10%) | called by muse, mutect2, varscan2
- JAK2 | c.1749G>T p.L583= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV67606438; called by muse, mutect2, varscan2
- KALRN | c.6057G>A p.V2019= (on ENST00000360013 / NM_001024660.4; = p.V322= on NM_007064.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 23/143 reads (16%) | catalogued as rs770046012, COSV52255163; called by muse, mutect2, varscan2
- KIF2B | c.45C>A p.P15= | Silent (SNP) | VAF 10/87 reads (11%) | catalogued as COSV52129824, COSV52135523; called by muse, mutect2, varscan2
- KLHL15 | c.363C>T p.C121= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as COSV60140129; called by muse, mutect2, varscan2
- KLK6 | c.411C>T p.S137= | Silent (SNP) | VAF 46/126 reads (37%) | catalogued as COSV59565449; called by muse, mutect2, varscan2
- KRT25 | c.435C>T p.I145= | Silent (SNP) | VAF 32/152 reads (21%) | catalogued as rs1004816398, COSV56444613; called by muse, mutect2, varscan2
- KRT36 | c.621C>A p.T207= | Silent (SNP) | VAF 53/190 reads (28%) | catalogued as COSV60203229; called by muse, mutect2, varscan2
- KRTAP27-1 | c.453C>T p.F151= | Silent (SNP) | VAF 60/196 reads (31%) | catalogued as rs781274963, COSV67000922; called by muse, mutect2, varscan2
- LDB3 | c.999G>A p.S333= | Silent (SNP) | VAF 24/110 reads (22%) | catalogued as rs1332348876, COSV53940707; called by muse, mutect2
- LHX9 | c.1059C>T p.L353= | Silent (SNP) | VAF 18/191 reads (9%) | catalogued as COSV61328341; called by muse, mutect2, varscan2
- MCM6 | c.1950G>A p.R650= | Silent (SNP) | VAF 9/72 reads (13%) | catalogued as COSV51466040; called by muse, mutect2, varscan2
- MOGAT2 | c.402T>A p.G134= | Silent (SNP) | VAF 66/261 reads (25%) | catalogued as COSV99549466; called by muse, mutect2, varscan2
- MPO | c.168G>A p.E56= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as rs749073976, COSV56563433; called by muse, mutect2, varscan2
- MRGPRX1 | c.420G>T p.A140= | Silent (SNP) | VAF 26/173 reads (15%) | catalogued as COSV57106964, COSV57107149; called by mutect2, varscan2
- MYH1 | c.5805C>T p.I1935= | Silent (SNP) | VAF 69/390 reads (18%) | catalogued as rs746682561, COSV56847312; called by muse, mutect2, varscan2
- NDUFB8 | c.240C>T p.D80= | Silent (SNP) | VAF 12/81 reads (15%) | catalogued as COSV54511730; called by muse, mutect2
- OR4D6 | c.228C>A p.I76= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as COSV55659642, COSV55661026; called by muse, mutect2, varscan2
- OR52E4 | c.186C>T p.F62= | Silent (SNP) | VAF 94/279 reads (34%) | catalogued as COSV57624527; called by muse, mutect2, varscan2
- PAPPA2 | c.4491C>T p.A1497= | Silent (SNP) | VAF 29/195 reads (15%) | catalogued as COSV100867766; called by muse, mutect2, varscan2
- PCDHA1 | c.1437G>A p.A479= | Silent (SNP) | VAF 78/245 reads (32%) | catalogued as rs140952598; called by muse, mutect2, varscan2
- PCDHGB4 | c.864C>G p.T288= | Silent (SNP) | VAF 12/89 reads (13%) | catalogued as COSV53937323; called by muse, mutect2, varscan2
- PGS1 | c.382C>T p.L128= | Silent (SNP) | VAF 23/119 reads (19%) | catalogued as COSV53144955; called by muse, mutect2, varscan2
- PLS3 | c.1653C>T p.S551= | Silent (SNP) | VAF 74/141 reads (52%) | catalogued as COSV56778074; called by muse, mutect2, varscan2
- PRDM9 | c.1782C>A p.V594= | Silent (SNP) | VAF 53/225 reads (24%) | catalogued as COSV57003857, COSV57005670; called by muse, mutect2, varscan2
- ROBO4 | c.246C>A p.L82= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as COSV60623557; called by muse, mutect2, varscan2
- RYR2 | c.3114G>T p.L1038= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV100769215; called by muse, mutect2
- S100A7L2 | c.279G>T p.V93= | Silent (SNP) | VAF 32/367 reads (9%) | catalogued as COSV64195039; called by muse, mutect2
- SERPINB13 | c.567G>A p.R189= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as rs866757068, COSV54028337; called by muse, mutect2, varscan2
- SHB | c.954C>T p.P318= | Silent (SNP) | VAF 35/128 reads (27%) | catalogued as COSV66628983; called by muse, mutect2, varscan2
- SLC38A7 | c.1080G>A p.E360= | Silent (SNP) | VAF 15/126 reads (12%) | catalogued as COSV99543723; called by muse, mutect2, varscan2
- SLIT1 | c.3702C>A p.A1234= | Silent (SNP) | VAF 18/97 reads (19%) | catalogued as COSV56588280; called by muse, mutect2, varscan2
- SNAP47 | c.387G>A p.R129= | Silent (SNP) | VAF 37/173 reads (21%) | catalogued as rs748177178, COSV59917679; called by muse, mutect2, varscan2
- SNTG1 | c.1464T>A p.A488= | Silent (SNP) | VAF 108/246 reads (44%) | catalogued as COSV52440201; called by muse, mutect2, varscan2
- SYCE1 | c.342G>A p.L114= (on ENST00000343131 / NM_001143764.3; = p.L78= on NM_130784.3) | Silent (SNP) | VAF 20/93 reads (22%) | catalogued as COSV58216942; called by muse, mutect2, varscan2
- SYT10 | c.1128G>T p.T376= | Silent (SNP) | VAF 17/88 reads (19%) | catalogued as COSV57339846, COSV57344129; called by muse, mutect2, varscan2
- TERF2 | c.774C>G p.T258= | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as COSV54747219; called by muse, mutect2, varscan2
- TLR4 | c.108T>A p.I36= | Silent (SNP) | VAF 46/187 reads (25%) | catalogued as COSV62923128; called by muse, mutect2, varscan2
- TLR4 | c.2148G>T p.V716= (on ENST00000355622 / NM_138554.5; = p.V676= on NM_003266.4) | Silent (SNP) | VAF 23/97 reads (24%) | catalogued as COSV62923132; called by muse, mutect2, varscan2
- TPSD1 | c.31C>T p.L11= | Silent (SNP) | VAF 48/231 reads (21%) | catalogued as COSV52975321; called by muse, mutect2, varscan2
- TRPS1 | c.303G>C p.P101= (on ENST00000220888 / NM_001330599.2; = p.P114= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 59/131 reads (45%) | catalogued as COSV55237978, COSV55249144; called by muse, mutect2, varscan2
- TXNRD2 | c.828G>T p.L276= | Silent (SNP) | VAF 24/89 reads (27%) | catalogued as COSV57632963; called by muse, mutect2, varscan2
- USH2A | c.11334A>T p.P3778= | Silent (SNP) | VAF 29/119 reads (24%) | catalogued as COSV56362040; called by muse, mutect2, varscan2
- VSX1 | c.570T>C p.D190= | Silent (SNP) | VAF 48/203 reads (24%) | catalogued as rs764614529, COSV65021577; called by muse, mutect2, varscan2
- WDR19 | c.1116A>T p.V372= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV56464751; called by muse, mutect2
- WDR90 | c.3624C>T p.T1208= | Silent (SNP) | VAF 18/143 reads (13%) | catalogued as rs201395848; called by muse, mutect2, varscan2
- WHRN | c.825G>T p.G275= | Silent (SNP) | VAF 26/137 reads (19%) | catalogued as COSV54330182; called by muse, mutect2, varscan2
- ZNF185 | c.372T>A p.A124= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as COSV59275604; called by muse, mutect2
- ZNF229 | c.2406G>A p.G802= | Silent (SNP) | VAF 27/84 reads (32%) | catalogued as COSV52161516; called by muse, mutect2, varscan2
- ZNF287 | c.495G>T p.V165= | Silent (SNP) | VAF 33/128 reads (26%) | catalogued as COSV67688401; called by muse, mutect2, varscan2
- ZNF676 | c.186C>A p.P62= (on ENST00000650058; = p.P30= on NM_001001411.3) | Silent (SNP) | VAF 14/190 reads (7%) | catalogued as COSV68092941; called by muse, mutect2
- AC024940.1 | n.5102G>T | RNA (SNP) | VAF 10/53 reads (19%) | called by muse, mutect2, varscan2
- ADARB2 | c.1865-1464G>T | Intron (SNP) | VAF 8/122 reads (7%) | catalogued as rs1384046169; called by muse, mutect2
- ADGRA1 | c.4-1275C>A | Intron (SNP) | VAF 8/34 reads (24%) | catalogued as COSV101192780; called by muse, mutect2, varscan2
- AL136982.4 | n.275C>G | RNA (SNP) | VAF 17/197 reads (9%) | called by muse, mutect2
- KNOP1P1 | n.251C>T | RNA (SNP) | VAF 5/38 reads (13%) | catalogued as rs1387404245; called by muse, mutect2, varscan2
- SNORD116-20 | n.53G>T | RNA (SNP) | VAF 35/399 reads (9%) | called by muse, mutect2
- ST6GALNAC6 | c.*257C>T | 3'UTR (SNP) | VAF 32/116 reads (28%) | catalogued as COSV52535398; called by muse, mutect2, varscan2
- TBX2 | chr17:61412152 C>A | 3'Flank (SNP) | VAF 7/29 reads (24%) | called by muse, mutect2, varscan2
- ZNF226 | c.236-477G>C | Intron (SNP) | VAF 11/103 reads (11%) | catalogued as COSV100335085; called by muse, mutect2, varscan2
- ZNF226 | c.236-476G>T | Intron (SNP) | VAF 11/103 reads (11%) | catalogued as rs779491863, COSV100335087; called by muse, mutect2, varscan2
